Somatic mutation profile of tumor specimen TCGA-CJ-6030-01A (aliquot TCGA-CJ-6030-01A-11D-1669-08) from TCGA case TCGA-CJ-6030, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 66.0 years (24,096 days).
Specimen TCGA-CJ-6030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 750835f0-f2e6-4226-a3c4-8e74cf340b6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6030-11A (Solid Tissue Normal), aliquot TCGA-CJ-6030-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7220bac-02ed-42ab-a43a-0f32fbe88282

The open-access MAF lists 118 somatic variants for this specimen: 94 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 23, Frame Shift Del 11, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869025642, CM014753, COSV56542964, COSV56545452; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5667C>A p.Y1889* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV64671754; called by muse, mutect2, varscan2
- ADAMTS13 | c.331-2A>G p.X111_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as CD152837, COSV63020388; called by mutect2, varscan2
- ASS1 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV61688667; called by muse, mutect2, varscan2
- BDP1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV62429685; called by muse, mutect2, varscan2
- BICRAL | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV58404044; called by muse, mutect2, varscan2
- C6orf47 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63263640; called by muse, mutect2, varscan2
- CALB1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55366843; called by muse, mutect2
- CD53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV54760419; called by muse, mutect2, varscan2
- CHML | c.1373T>A p.V458E | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59362971; called by muse, mutect2, varscan2
- COBLL1 | c.1579G>A p.D527N (on ENST00000392717; = p.D489N on NM_014900.5) | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV52064426; called by muse, mutect2, varscan2
- COL11A1 | c.3277-1G>T p.X1093_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62175632; called by muse, mutect2
- COL6A6 | c.1664A>G p.E555G | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV62019774; called by muse, mutect2, varscan2
- CTCFL | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54771648; called by muse, mutect2, varscan2
- DIS3 | c.2600A>G p.Y867C | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV66705824; called by muse, mutect2, varscan2
- DMKN | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV60085173; called by muse, mutect2, varscan2
- DNA2 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64427781; called by muse, mutect2, varscan2
- EP300 | c.5279A>G p.K1760R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54328413; called by muse, mutect2, varscan2
- EYS | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV60979099; called by muse, mutect2
- FAM227B | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54807099; called by muse, mutect2, varscan2
- FBN3 | c.2153C>G p.S718* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV54455463, COSV99560463; called by muse, mutect2, varscan2
- FZD1 | c.1602G>T p.M534I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV55309312; called by muse, mutect2, varscan2
- GALNT13 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV67212699; called by muse, mutect2, varscan2
- HEXA | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV51505548; called by muse, mutect2, varscan2
- HIP1 | c.2967G>T p.E989D | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61183989; called by muse, mutect2
- HMCN1 | c.6849del p.L2284Cfs*9 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as COSV54884107, COSV54888975; called by mutect2, pindel, varscan2
- HTR1E | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59507146; called by muse, mutect2, varscan2
- INSYN2A | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs551807342, COSV54732908; called by muse, mutect2, varscan2
- ISL1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV57932730; called by muse, mutect2, varscan2
- JAKMIP3 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53820978, COSV53823430; called by muse, mutect2, varscan2
- KDM5D | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58736143; called by muse, mutect2, varscan2
- KLHL1 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV64768337; called by muse, mutect2, varscan2
- LRIF1 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV63896847; called by muse, mutect2, varscan2
- LSMEM2 | c.361+2T>A p.X121_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV57112880; called by muse, mutect2, varscan2
- LYPD3 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54987956; called by muse, mutect2, varscan2
- MCM5 | c.1747A>C p.K583Q | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.219); catalogued as COSV53345321; called by muse, mutect2, varscan2
- MPC2 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54796424; called by muse, mutect2
- NAA10 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63131089; called by muse, mutect2, varscan2
- NARF | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59110856; called by muse, mutect2, varscan2
- NFE2L1 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV62582879, COSV62582993; called by muse, mutect2, varscan2
- NOTCH4 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66679391; called by muse, mutect2, varscan2
- NPTX1 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60774490; called by muse, mutect2, varscan2
- NUP160 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV65853814; called by muse, varscan2
- OR1C1 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV68715508; called by muse, mutect2, varscan2
- PANK2 | c.1420A>C p.N474H (on ENST00000316562 / NM_153638.3; = p.N183H on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as CD060643, COSV57253357; called by muse, mutect2, varscan2
- POLK | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1390061264, COSV54032993; called by muse, mutect2, varscan2
- PPFIA4 | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV55312661; called by muse, mutect2, varscan2
- PPIP5K2 | c.2714A>C p.N905T | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV58603445; called by muse, mutect2, varscan2
- PRRC2A | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63224368; called by muse, mutect2, varscan2
- RAB3GAP2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV52964818; called by muse, mutect2, varscan2
- RIMKLB | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV55235755; called by muse, mutect2, varscan2
- RPGRIP1 | c.3040C>T p.Q1014* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs751283891, COSV52846518; called by muse, mutect2, varscan2
- RREB1 | c.4643C>G p.T1548S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1469851927, COSV58554940; called by muse, varscan2
- RXRB | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59494456; called by muse, mutect2, varscan2
- SEC16B | c.2398T>C p.S800P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV57624156; called by muse, mutect2, varscan2
- SECISBP2L | c.1955C>G p.P652R (on ENST00000559471 / NM_001193489.2; = p.P607R on NM_014701.4) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55933315; called by muse, mutect2, varscan2
- SHOC1 | c.3545T>A p.V1182E | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV59498518; called by muse, mutect2, varscan2
- SHROOM3 | c.2201C>G p.S734C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV56024870; called by muse, mutect2, varscan2
- SKP2 | c.990A>T p.E330D | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV57040802; called by muse, mutect2, varscan2
- SLITRK6 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV68389598; called by muse, mutect2, varscan2
- SPTA1 | c.6992A>G p.K2331R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100935708, COSV63750142; called by muse, mutect2, varscan2
- SRGAP1 | c.186A>C p.E62D | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV61895376; called by muse, mutect2, varscan2
- SRGAP1 | c.2434del p.Q812Kfs*22 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as COSV100754200; called by mutect2, pindel, varscan2
- STPG2 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs200220026; called by muse, mutect2, varscan2
- SYNM | c.3563T>C p.I1188T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV50440930; called by muse, mutect2, varscan2
- TACC2 | c.4853T>C p.F1618S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57749236; called by muse, mutect2, varscan2
- TECRL | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67085995, COSV67087812; called by muse, mutect2, varscan2
- TINAG | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767247771, COSV52506849; called by muse, mutect2, varscan2
- TIPRL | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63207690; called by muse, mutect2, varscan2
- TRAF5 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV54821575; called by muse, mutect2, varscan2
- TRIP12 | c.5204C>A p.S1735* | Nonsense Mutation (SNP) | VAF 56/256 reads (22%) | catalogued as COSV52260508; called by muse, mutect2, varscan2
- TSPAN11 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53816849; called by muse, mutect2, varscan2
- TUBB | c.10A>C p.I4L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58357386; called by muse, mutect2, varscan2
- VPS39 | c.392A>T p.E131V (on ENST00000348544 / NM_001301138.2; = p.E120V on NM_015289.5) | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV58788342; called by muse, mutect2, varscan2
- XCR1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV58569214; called by muse, mutect2, varscan2
- XPOT | c.2534G>T p.C845F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60344324; called by muse, mutect2, varscan2
- YIF1B | c.789G>T p.M263I (on ENST00000339413 / NM_001039673.3; = p.M248I on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.318); catalogued as COSV56649828; called by muse, varscan2
- ZNF404 | c.1581del p.E527Dfs*25 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV100182717; called by mutect2, pindel, varscan2
- ZNF764 | c.253T>G p.W85G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs369068123; called by muse, mutect2
- ZYG11B | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53750861; called by muse, mutect2, varscan2
- ADGRV1 | c.4999dup p.S1667Ffs*22 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- BTN1A1 | c.83_84insT p.F29Lfs*2 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- FAM153A | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by mutect2, varscan2
- ICE1 | c.2298del p.D767Ifs*5 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.699_712del p.N233Kfs*7 (on ENST00000619416 / NM_001244190.2; = p.N248Kfs*7 on NM_014749.5) | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- LRP1 | c.2913_2914+5del p.X971_splice | Splice Site (DEL) | VAF 23/127 reads (18%) | called by mutect2, pindel, varscan2
- MAGI3 | c.2330del p.D777Vfs*17 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- MAP10 | c.2892del p.T965Qfs*18 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- MED13 | c.3407del p.N1136Tfs*11 | Frame Shift Del (DEL) | VAF 45/227 reads (20%) | called by mutect2, pindel, varscan2
- NIT2 | c.335del p.K112Rfs*21 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- PBRM1 | c.424dup p.D142Gfs*9 | Frame Shift Ins (INS) | VAF 37/134 reads (28%) | called by mutect2, pindel, varscan2
- RBM39 | c.767del p.S256Yfs*6 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- TUBGCP3 | c.1590del p.Q531Rfs*32 | Frame Shift Del (DEL) | VAF 25/118 reads (21%) | called by mutect2, pindel, varscan2
- VGLL2 | c.251dup p.C85Lfs*17 | Frame Shift Ins (INS) | VAF 36/204 reads (18%) | called by pindel, varscan2
- AMER2 | c.1935G>A p.L645= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV63436471; called by muse, mutect2, varscan2
- AP002748.5 | c.831C>G p.A277= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV59147375; called by muse, mutect2, varscan2
- CAPN3 | c.1617C>T p.N539= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV58820021; called by muse, mutect2, varscan2
- CELF5 | c.648G>A p.K216= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV53010643; called by muse, mutect2, varscan2
- CYP2F1 | c.735C>T p.I245= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs139489388; called by muse, mutect2, varscan2
- DNAJC13 | c.2367A>G p.E789= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as COSV53447038; called by muse, mutect2
- ELAVL2 | c.354T>C p.S118= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV56358819; called by muse, mutect2, varscan2
- ENTPD1 | c.861T>C p.Y287= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV64600545; called by muse, mutect2, varscan2
- HMCES | c.169C>T p.L57= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV59112856; called by muse, mutect2, varscan2
- JTB | c.24T>A p.P8= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV55131619; called by muse, mutect2, varscan2
- LMNB1 | c.1440C>T p.V480= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV54396941; called by muse, mutect2, varscan2
- MKI67 | c.1239T>G p.T413= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV64073118; called by muse, mutect2, varscan2
- MORC3 | c.1092T>C p.T364= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV68687926; called by muse, mutect2, varscan2
- NSD1 | c.6576C>T p.F2192= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV61772176; called by muse, mutect2, varscan2
- PDCL2 | c.270A>G p.G90= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1363487638, COSV55259611; called by muse, mutect2
- PSMB8 | c.777A>T p.V259= (on ENST00000374882 / NM_148919.4; = p.V255= on NM_004159.5) | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV62753970; called by muse, mutect2, varscan2
- RUSC2 | c.1212A>T p.L404= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV63427859; called by muse, mutect2, varscan2
- SEC14L3 | c.1104C>A p.T368= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV53178397; called by muse, mutect2, varscan2
- SRCAP | c.8061A>T p.P2687= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV52668865; called by muse, mutect2, varscan2
- STK11IP | c.96C>T p.S32= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV55246324; called by muse, mutect2, varscan2
- SULT1E1 | c.822A>G p.K274= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV56946078; called by muse, mutect2, varscan2
- TECRL | c.75A>T p.I25= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as COSV67086006; called by muse, mutect2, varscan2
- TM4SF19 | c.432C>T p.F144= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV56556334; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2290T>A | Intron (SNP) | VAF 16/89 reads (18%) | catalogued as COSV54094507; called by muse, mutect2, varscan2
